Gene-level copy-number profile of tumor specimen TCGA-AG-3608-01A from TCGA case TCGA-AG-3608, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.4 years (29,008 days).
Specimen TCGA-AG-3608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b2b1b0c3-a5c4-4747-b135-b8a8ecebe892.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3608-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ddda229-0dd2-4465-be97-c5fc1917f2de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,484; copy number 2: 48,647; copy number 3: 7,700; copy number 5: 968.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3608-01): tumor purity 0.74, ploidy 2.08, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:66,547,179–67,521,844, 16 genes (within-gene range 0–2): LCTL, LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 968 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:24,931,840–64,313,132, 968 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,484. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
